Somatic mutation profile of tumor specimen TCGA-78-7536-01A (aliquot TCGA-78-7536-01A-11D-2063-08) from TCGA case TCGA-78-7536, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.0 years (25,558 days).
Specimen TCGA-78-7536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7582bc7-5fbf-41d4-b50a-635838ca7404.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7536-10A (Blood Derived Normal), aliquot TCGA-78-7536-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1da591c2-45a1-4912-99ef-d797969bedad

The open-access MAF lists 673 somatic variants for this specimen: 512 protein-altering or splice-affecting, 148 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 430, Silent 148, Nonsense Mutation 38, Splice Site 18, Frame Shift Del 14, Intron 6, RNA 6, Splice Region 4, Frame Shift Ins 3, Translation Start Site 2, In Frame Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.809T>G p.F270C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA13 | c.6820C>A p.L2274I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.164); catalogued as COSV70026054, COSV70026327; called by muse, mutect2, varscan2
- ABCA4 | c.3490A>G p.K1164E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV64671328; called by muse, mutect2, varscan2
- ABCA8 | c.3331G>T p.G1111* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52195150; called by muse, varscan2
- ABCC1 | c.2547G>T p.M849I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV60681048; called by muse, mutect2, varscan2
- ABHD2 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs201203844, COSV61772944; called by muse, mutect2, varscan2
- ACAD11 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs749588144, COSV53893904; called by muse, mutect2, varscan2
- ACTA1 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.027); catalogued as COSV64202925; called by muse, mutect2, varscan2
- ACTN2 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745317077, COSV63972376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.3080C>G p.S1027C | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV61256353, COSV61277339; called by muse, mutect2, varscan2
- ADAMTS12 | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61256356; called by muse, mutect2, varscan2
- ADAMTS20 | c.2554C>A p.P852T | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as rs771270670, COSV67127055; called by muse, mutect2, varscan2
- ADGRB3 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.981); catalogued as COSV65384330; called by muse, mutect2, varscan2
- ADGRD1 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.255); catalogued as COSV55439677; called by muse, mutect2
- ADGRG6 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV99748522; called by muse, mutect2, varscan2
- ADGRG7 | c.1725G>T p.W575C | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56293993; called by muse, mutect2, varscan2
- ADGRL3 | c.656C>A p.S219Y (on ENST00000506720 / NM_001322402.2; = p.S151Y on NM_015236.6) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV72266145; called by mutect2, varscan2
- AHNAK | c.9511G>C p.D3171H | Missense Mutation (SNP) | VAF 211/387 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57204781; called by muse, mutect2, varscan2
- AKAP3 | c.1864G>T p.V622F | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV57414321; called by muse, mutect2, varscan2
- AKAP3 | c.1349del p.G450Vfs*23 | Frame Shift Del (DEL) | VAF 59/96 reads (61%) | catalogued as COSV99075497; called by mutect2, pindel, varscan2
- AKNAD1 | c.1645T>C p.C549R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV62195228; called by muse, mutect2, varscan2
- AKNAD1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as COSV62195242; called by muse, mutect2, varscan2
- AKT3 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV55608845; called by muse, mutect2, varscan2
- ALDH8A1 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55640331; called by muse, mutect2, varscan2
- ALKBH1 | c.1153A>T p.I385L | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs770652409, COSV53658937; called by muse, mutect2, varscan2
- ALX4 | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61324972, COSV61326123; called by muse, mutect2, varscan2
- AMOTL1 | c.2690G>T p.G897V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV58565245; called by muse, mutect2, varscan2
- ANGPTL5 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57531987; called by muse, mutect2, varscan2
- ANK1 | c.4139C>A p.T1380K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV55873916, COSV99225499; called by muse, mutect2, varscan2
- ANK3 | c.4022C>T p.T1341I (on ENST00000280772 / NM_001320874.2; = p.T475I on NM_001149.3) | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55045687; called by muse, mutect2, varscan2
- APBA2 | c.1218G>T p.R406S | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.18); catalogued as COSV104430877, COSV67104247; called by muse, mutect2, varscan2
- ARAP2 | c.2452G>T p.A818S | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV58283028; called by muse, mutect2, varscan2
- ARHGAP20 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52807149; called by muse, mutect2, varscan2
- ARHGAP24 | c.2029G>A p.E677K (on ENST00000395184 / NM_001025616.3; = p.E584K on NM_031305.3) | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.985); catalogued as COSV51986965; called by muse, varscan2
- ARPP21 | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV51792708; called by muse, mutect2, varscan2
- ASXL3 | c.3419C>A p.P1140Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.467); catalogued as rs201152513; called by muse, mutect2, varscan2
- ATAD2B | c.3106G>T p.E1036* | Nonsense Mutation (SNP) | VAF 39/64 reads (61%) | catalogued as COSV53195556; called by muse, mutect2, varscan2
- ATG9A | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 40/67 reads (60%) | catalogued as COSV54693272; called by muse, mutect2, varscan2
- B4GALT4 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.159); catalogued as COSV63295534; called by muse, mutect2
- BCAS3 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.136); catalogued as COSV66770377; called by muse, mutect2, varscan2
- BMT2 | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 85/97 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51774917; called by muse, mutect2, varscan2
- BPIFB4 | c.675G>T p.T225= | Splice Region (SNP) | VAF 28/77 reads (36%) | catalogued as COSV64950696, COSV64950757; called by muse, mutect2, varscan2
- C10orf90 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52949979; called by muse, mutect2, varscan2
- C10orf90 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV52949999; called by muse, mutect2, varscan2
- C11orf53 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV54721027; called by muse, mutect2, varscan2
- C8A | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); catalogued as COSV63483201; called by muse, mutect2, varscan2
- C9orf131 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV56609773; called by muse, mutect2, varscan2
- CACNA1C | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs377345545, COSV59696262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.1165G>T p.V389F | Missense Mutation (SNP) | VAF 87/116 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV100221862; called by muse, mutect2, varscan2
- CACNA1E | c.3886T>C p.Y1296H | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62383577; called by muse, mutect2, varscan2
- CADM2 | c.592G>T p.G198* (on ENST00000407528 / NM_001167674.2; = p.G200* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 21/28 reads (75%) | catalogued as COSV67359023, COSV67362296; called by muse, mutect2, varscan2
- CALCA | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.344); catalogued as COSV59029136; called by muse, mutect2, varscan2
- CAND1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV73338545; called by muse, mutect2, varscan2
- CAPZA3 | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV56849416; called by muse, mutect2, varscan2
- CARD6 | c.2207C>G p.T736S | Missense Mutation (SNP) | VAF 200/425 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV54564388; called by muse, mutect2, varscan2
- CASP1 | c.1163C>A p.T388N (on ENST00000436863 / NM_033292.4; = p.T367N on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52826889; called by muse, mutect2, varscan2
- CBLB | c.1994A>G p.Y665C | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1200851467, COSV51421940; called by muse, mutect2, varscan2
- CBLN4 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV50352150, COSV99290731; called by muse, mutect2, varscan2
- CC2D1B | c.1502C>G p.P501R | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52558880; called by muse, mutect2, varscan2
- CCDC141 | c.3923A>T p.K1308M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV55369470; called by muse, mutect2, varscan2
- CCL20 | c.243G>C p.W81C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62591186; called by muse, mutect2, varscan2
- CCL21 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV52398614; called by muse, mutect2, varscan2
- CCL7 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1223491186, COSV52336622; called by muse, mutect2, varscan2
- CCR3 | c.1016C>G p.T339S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV62461752; called by muse, mutect2, varscan2
- CD109 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54645794; called by muse, mutect2, varscan2
- CD163L1 | c.861C>A p.C287* | Nonsense Mutation (SNP) | VAF 56/126 reads (44%) | catalogued as COSV58011687; called by muse, varscan2
- CD1C | c.977A>C p.H326P | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV63805754; called by muse, varscan2
- CD248 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60935797, COSV60937390, COSV60938104; called by muse, mutect2, varscan2
- CD5L | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63821174, COSV63821298; called by muse, mutect2, varscan2
- CDC25C | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 75/99 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV60398431; called by muse, mutect2, varscan2
- CDH18 | c.1240A>T p.N414Y | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56904026; called by muse, mutect2, varscan2
- CDH7 | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV59882041, COSV59891256; called by muse, mutect2, varscan2
- CDH9 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50253684, COSV50434304; called by muse, mutect2, varscan2
- CERKL | c.803C>A p.A268D (on ENST00000339098 / NM_001030311.2; = p.A242D on NM_201548.5) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59203830; called by muse, mutect2, varscan2
- CFAP251 | c.1591T>C p.S531P | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56608325; called by muse, mutect2, varscan2
- CGREF1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV53148522, COSV53150360; called by muse, mutect2, varscan2
- CHAMP1 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1555379989, COSV63521812; called by muse, mutect2, varscan2
- CHD7 | c.4810A>T p.S1604C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV71107432; called by muse, mutect2, varscan2
- CHORDC1 | c.866A>T p.K289M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as rs180930667, COSV57705482; called by muse, mutect2, varscan2
- CHRD | c.2573C>A p.P858H | Missense Mutation (SNP) | VAF 72/97 reads (74%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.547); catalogued as COSV52605784; called by muse, mutect2, varscan2
- CHST4 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58296548; called by muse, mutect2, varscan2
- CHST5 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60337220; called by muse, mutect2, varscan2
- CIB3 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV54165515; called by muse, mutect2, varscan2
- CIT | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 61/239 reads (26%) | catalogued as COSV55861119; called by muse, mutect2, varscan2
- CLCA4 | c.1904C>A p.S635* | Nonsense Mutation (SNP) | VAF 62/130 reads (48%) | catalogued as COSV55366558; called by muse, mutect2, varscan2
- CLCC1 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs747500013, COSV56762182; called by muse, mutect2, varscan2
- CLCN7 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51974596; called by muse, varscan2
- CNR1 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62986537; called by muse, mutect2, varscan2
- CNR1 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV62986541; called by muse, mutect2, varscan2
- CNTN1 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61636583; called by muse, mutect2, varscan2
- CNTNAP1 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.98); catalogued as rs780146066, COSV52848154; called by muse, mutect2, varscan2
- COBL | c.3619C>T p.P1207S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs1319094826, COSV54339189; called by muse, mutect2, varscan2
- COL14A1 | c.4777G>C p.G1593R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52847910, COSV99918427; called by muse, mutect2, varscan2
- COL20A1 | c.3749G>A p.W1250* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs867867793, COSV58912314; called by muse, mutect2, varscan2
- COL5A1 | c.3449G>A p.G1150D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65665534; called by muse, mutect2, varscan2
- COL5A2 | c.4122T>A p.Y1374* | Nonsense Mutation (SNP) | VAF 20/417 reads (5%) | catalogued as COSV66407390; called by muse, mutect2
- COL6A6 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.305); catalogued as rs752036403, COSV62018779; called by muse, mutect2, varscan2
- COQ8B | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV54573429, COSV54575159; called by muse, mutect2, varscan2
- CPNE4 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV70189858, COSV70190380; called by muse, mutect2, varscan2
- CR2 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs1168627412, COSV65506181; called by muse, mutect2, varscan2
- CRB1 | c.3407G>T p.G1136V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66328824; called by muse, mutect2, varscan2
- CRNN | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55120813, COSV55120864; called by muse, mutect2, varscan2
- CSMD3 | c.1464T>A p.D488E (on ENST00000297405 / NM_001363185.1; = p.D384E on NM_052900.3) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1221589463, COSV52110701; called by muse, mutect2, varscan2
- CSPG4 | c.3724G>C p.V1242L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV57891121; called by muse, mutect2, varscan2
- CSPP1 | c.1832A>G p.K611R (on ENST00000676605; = p.K570R on NM_024790.6) | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.075); catalogued as rs759406937, COSV51580726; called by muse, mutect2, varscan2
- CST9 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.076); catalogued as COSV65402392; called by muse, mutect2, varscan2
- CST9 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.134); catalogued as COSV65402396; called by muse, mutect2, varscan2
- CTLA4 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV55591821; called by muse, mutect2, varscan2
- CTLA4 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 220/264 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV55591829; called by muse, mutect2, varscan2
- CTNND2 | c.2844C>G p.N948K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV58867923; called by muse, mutect2, varscan2
- CUBN | c.8846T>A p.V2949D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as rs757571855, COSV64708736; called by muse, mutect2
- CUBN | c.3431A>G p.K1144R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV64708741; called by muse, mutect2
- CUX2 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55625415; called by muse, mutect2, varscan2
- CUZD1 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV59025667; called by muse, mutect2, varscan2
- CYP11B2 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs776680043, COSV100010907, COSV59994558; called by muse, mutect2, varscan2
- CYP4F12 | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV61172479; called by muse, mutect2, varscan2
- DAB1 | c.1177C>A p.Q393K (on ENST00000371231; = p.Q360K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.304); catalogued as COSV64690477; called by muse, mutect2, varscan2
- DACT1 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV60019545, COSV60022757; called by muse, mutect2, varscan2
- DAOA | c.44+1G>T p.X15_splice | Splice Site (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100298899; called by muse, mutect2, varscan2
- DCAF12L1 | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64421219; called by muse, mutect2, varscan2
- DCC | c.3608C>A p.T1203N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71426771, COSV71435254; called by muse, mutect2, varscan2
- DDIAS | c.2701C>A p.P901T | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV61271569; called by muse, mutect2, varscan2
- DENND2A | c.1506G>C p.R502S | Missense Mutation (SNP) | VAF 148/180 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV52048153; called by muse, mutect2, varscan2
- DESI2 | c.70A>T p.I24F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV55640212; called by muse, mutect2, varscan2
- DIAPH3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57365397; called by muse, mutect2, varscan2
- DIDO1 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV56614745, COSV99826145; called by muse, mutect2, varscan2
- DLC1 | c.2109G>T p.M703I (on ENST00000276297 / NM_001348081.2; = p.M266I on NM_006094.5) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52291637; called by muse, mutect2, varscan2
- DLG1 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 123/140 reads (88%) | catalogued as COSV58378337; called by muse, mutect2, varscan2
- DLGAP2 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101422634; called by muse, mutect2, varscan2
- DNAH8 | c.4075C>A p.Q1359K | Missense Mutation (SNP) | VAF 89/114 reads (78%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV59427834; called by muse, mutect2, varscan2
- DNAH9 | c.10053+1G>C p.X3351_splice | Splice Site (SNP) | VAF 27/48 reads (56%) | catalogued as COSV52335939; called by muse, mutect2, varscan2
- DNER | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59160709; called by muse, mutect2, varscan2
- DPF2 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV52887929; called by muse, mutect2, varscan2
- DPY19L2 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV60541497; called by muse, mutect2, varscan2
- DPYD | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as COSV64591629; called by muse, mutect2, varscan2
- DYSF | c.5080G>C p.D1694H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50271642, COSV50349922; called by muse, mutect2, varscan2
- EBF1 | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58168753; called by muse, mutect2, varscan2
- EEF1B2 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 147/260 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99261424; called by muse, mutect2, varscan2
- EEF1B2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 145/261 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157195650, COSV99261425; called by muse, mutect2, varscan2
- EGF | c.1312G>C p.G438R | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54476019; called by muse, mutect2, varscan2
- EPHA5 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56643924, COSV99901013; called by muse, mutect2, varscan2
- EPHA5 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99901014; called by muse, mutect2, varscan2
- ESCO1 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV52518493; called by muse, mutect2, varscan2
- ESPL1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs199588886, COSV57757662; called by muse, mutect2, varscan2
- ESR1 | c.1622T>A p.L541Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52782976; called by muse, mutect2, varscan2
- EXPH5 | c.231G>C p.M77I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56199229; called by muse, mutect2, varscan2
- FADS3 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53877470; called by muse, mutect2, varscan2
- FAM217B | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV62563878; called by muse, mutect2, varscan2
- FAM47A | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100650056; called by muse, mutect2, varscan2
- FAM76A | c.883A>T p.S295C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV50548780; called by muse, mutect2, varscan2
- FARP2 | c.288G>C p.W96C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV50869244; called by muse, mutect2, varscan2
- FASLG | c.846A>C p.*282Yext*23 | Nonstop Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV60679781; called by muse, mutect2, varscan2
- FAT3 | c.7365C>A p.N2455K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV99970579; called by muse, varscan2
- FAT3 | c.7366C>A p.H2456N | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.501); catalogued as COSV99970580; called by muse, varscan2
- FAT3 | c.10972C>G p.P3658A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53079936; called by muse, mutect2, varscan2
- FAT3 | c.11129G>T p.S3710I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV53079955; called by muse, mutect2, varscan2
- FAT3 | c.12364T>A p.C4122S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53079985; called by muse, mutect2
- FAXC | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67601518; called by muse, mutect2, varscan2
- FBLN2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV55481101; called by muse, mutect2, varscan2
- FBXW4 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.182); catalogued as COSV58706843; called by muse, mutect2, varscan2
- FCHO2 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs574187088, COSV59270201; called by mutect2, varscan2
- FLG | c.8734T>G p.S2912A | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV64237342; called by muse, mutect2, varscan2
- FLG | c.3970G>A p.D1324N | Missense Mutation (SNP) | VAF 204/435 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs780192750, COSV64237347; called by muse, mutect2, varscan2
- FOXK1 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61064506; called by muse, mutect2, varscan2
- FTHL17 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV63266442; called by muse, mutect2, varscan2
- GABRR3 | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.071); catalogued as COSV72084009; called by muse, mutect2, varscan2
- GDF5 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100976920, COSV65499591; called by muse, mutect2, varscan2
- GGH | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52649452; called by muse, mutect2, varscan2
- GJB4 | c.589T>C p.C197R | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58355553; called by muse, mutect2, varscan2
- GLG1 | c.1625G>C p.C542S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52664230; called by muse, mutect2, varscan2
- GM2A | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1339135426, COSV64095202; called by muse, mutect2, varscan2
- GOLGA6B | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1489551369, COSV69769893; called by muse, mutect2, varscan2
- GPATCH1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs758670399, COSV50111529; called by muse, mutect2, varscan2
- GPBP1L1 | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV51967158; called by muse, mutect2, varscan2
- GRIA4 | c.1469T>A p.V490D | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56883657; called by muse, mutect2, varscan2
- GRID1 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60015532; called by muse, mutect2, varscan2
- GSDMC | c.1427A>T p.E476V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52693469; called by muse, mutect2, varscan2
- GYS2 | c.1574C>A p.P525H | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53920822; called by muse, mutect2, varscan2
- HCN1 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs180790607, COSV57495369, COSV57501466; called by muse, mutect2, varscan2
- HECW1 | c.3100-2A>G p.X1034_splice | Splice Site (SNP) | VAF 55/81 reads (68%) | catalogued as COSV67822894; called by muse, mutect2, varscan2
- HECW1 | c.3973G>A p.V1325M | Missense Mutation (SNP) | VAF 62/73 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67822900; called by muse, mutect2, varscan2
- HECW2 | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53650571, COSV53663626; called by muse, mutect2, varscan2
- HEPH | c.3044A>G p.E1015G (on ENST00000343002; = p.E748G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV57959684; called by muse, mutect2, varscan2
- HGF | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1355838479, COSV55945869; called by muse, mutect2, varscan2
- HGF | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV55945880; called by muse, mutect2, varscan2
- HIVEP1 | c.7213C>T p.H2405Y | Missense Mutation (SNP) | VAF 140/157 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV65098984; called by muse, mutect2, varscan2
- HRNR | c.6629G>C p.S2210T | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as COSV64254932; called by muse, mutect2
- HYDIN | c.4459G>T p.G1487* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV66830115; called by muse, mutect2, varscan2
- IFNAR1 | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54251028; called by muse, mutect2, varscan2
- IGHV4-31 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 211/702 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.7); catalogued as rs530762790; called by muse, mutect2, varscan2
- IGLV8-61 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs566370819, COSV66502554; called by muse, varscan2
- IL7R | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57406159; called by muse, mutect2, varscan2
- INTS1 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67176481; called by mutect2, varscan2
- IQCD | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV55320376; called by muse, mutect2, varscan2
- ITGAV | c.2153A>G p.K718R | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53709546; called by muse, mutect2
- ITGB8 | c.636-1G>T p.X212_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV56005360; called by muse, mutect2, varscan2
- ITIH1 | c.303C>A p.A101= | Splice Region (SNP) | VAF 38/47 reads (81%) | catalogued as COSV56252334; called by muse, mutect2, varscan2
- ITIH2 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV64432087, COSV64432959; called by muse, mutect2, varscan2
- JAML | c.239C>T p.P80L (on ENST00000356289 / NM_001098526.2; = p.P70L on NM_153206.3) | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52626581; called by muse, mutect2, varscan2
- JPH1 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 119/243 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60608865, COSV60610314; called by muse, mutect2, varscan2
- KANSL1L | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs1476632755, COSV55989780; called by muse, mutect2, varscan2
- KCND3 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56175932, COSV56191636; called by muse, mutect2, varscan2
- KCNH2 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 76/87 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs376319070, COSV51127474; called by muse, mutect2, varscan2
- KCNK13 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 84/110 reads (76%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV56410841, COSV56416329; called by muse, mutect2, varscan2
- KCTD18 | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.153); catalogued as COSV63343960; called by muse, mutect2, varscan2
- KDM6A | c.3961G>T p.G1321W | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV65037435; called by muse, mutect2, varscan2
- KIAA0319L | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57842389; called by muse, mutect2
- KIAA1549L | c.1256T>G p.L419W (on ENST00000321505; = p.L716W on NM_012194.3) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV55770062; called by muse, mutect2, varscan2
- KIF2B | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 28/36 reads (78%) | catalogued as COSV52127382; called by muse, mutect2, varscan2
- KIF5A | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs763336788, COSV54051933; called by muse, mutect2, varscan2
- KIF5A | c.2300C>A p.T767K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.242); catalogued as COSV54051942, COSV54057232; called by muse, mutect2, varscan2
- KMT2B | c.3772A>G p.K1258E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55857661; called by muse, mutect2, varscan2
- KMT2C | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51325762; called by muse, mutect2, varscan2
- KRT1 | c.1408A>C p.N470H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52865144; called by muse, mutect2, varscan2
- L3MBTL1 | c.1218G>T p.W406C (on ENST00000418998 / NM_001377303.1; = p.W316C on NM_015478.7) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64227936, COSV64229720; called by muse, mutect2, varscan2
- LAMA1 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67532680; called by muse, mutect2, varscan2
- LAMC1 | c.1589A>C p.Q530P | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV51133321; called by muse, mutect2, varscan2
- LARS1 | c.1355A>G p.Q452R (on ENST00000394434 / NM_020117.11; = p.Q425R on NM_016460.3) | Missense Mutation (SNP) | VAF 174/206 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV50972502; called by muse, mutect2, varscan2
- LASP1 | c.402C>G p.S134R | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.226); catalogued as rs755621366, COSV100530309, COSV58802678; called by muse, mutect2, varscan2
- LCN8 | c.285C>A p.F95L (on ENST00000612714 / NM_001345934.1; = p.F72L on NM_178469.3) | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60209357, COSV60211288; called by muse, mutect2, varscan2
- LHX8 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV53954620; called by muse, mutect2, varscan2
- LPL | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV60930144; called by muse, mutect2, varscan2
- LRFN1 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50434729; called by muse, mutect2, varscan2
- LRP1 | c.5140G>T p.G1714W | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54502978; called by muse, mutect2, varscan2
- LRP4 | c.3463G>T p.G1155W | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66134185; called by muse, mutect2, varscan2
- LRRC4 | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 111/124 reads (90%) | catalogued as COSV50813356, COSV50818284; called by muse, mutect2, varscan2
- LRRC43 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs773144736, COSV60288150; called by muse, mutect2, varscan2
- LRRTM4 | c.1389G>T p.M463I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.052); catalogued as COSV69139123; called by muse, mutect2, varscan2
- MAF1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.336); catalogued as COSV100075733, COSV59362668; called by muse, mutect2, varscan2
- MAGEA11 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100290624, COSV60753938, COSV60756234; called by muse, mutect2, varscan2
- MAGEB2 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs368299444, COSV66780239; called by muse, mutect2, varscan2
- MAGEC1 | c.677A>T p.E226V | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53568623; called by muse, varscan2
- MAGEC1 | c.887A>T p.E296V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV53568634; called by muse, varscan2
- MAGEL2 | c.3168T>A p.D1056E | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV58566028; called by muse, mutect2, varscan2
- MAGI3 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV56828995; called by muse, mutect2, varscan2
- MAP1S | c.1654A>T p.K552* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as COSV60721809; called by muse, mutect2, varscan2
- MAP2 | c.2898G>T p.K966N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs773209563, COSV52282451; called by muse, mutect2, varscan2
- MAP3K5 | c.2367A>T p.E789D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV62887320; called by muse, mutect2, varscan2
- MARCHF4 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99814756; called by muse, mutect2, varscan2
- MCF2L | c.1087G>A p.V363I (on ENST00000375608; = p.V331I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV100982914; called by muse, mutect2, varscan2
- MCM5 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs1389092860, COSV53345039; called by muse, mutect2, varscan2
- METTL9 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV63961240; called by muse, mutect2, varscan2
- MIA2 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV54489184; called by muse, mutect2, varscan2
- MIER1 | c.943G>T p.V315F (on ENST00000355356 / NM_001077701.3; = p.V332F on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62529259, COSV62531774; called by muse, mutect2, varscan2
- MIGA2 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776352320, COSV99477853; called by muse, mutect2, varscan2
- MN1 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs568489325, COSV56556281; called by muse, mutect2, varscan2
- MR1 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51579924; called by muse, mutect2, varscan2
- MROH2B | c.2603C>A p.A868D | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68181420; called by muse, mutect2, varscan2
- MRPL19 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs200525291; called by muse, mutect2, varscan2
- MRPL50 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 88/108 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV66405971; called by muse, mutect2, varscan2
- MRPS22 | c.183C>G p.S61R (on ENST00000310776 / NM_001363893.1; = p.S62R on NM_020191.4) | Missense Mutation (SNP) | VAF 115/125 reads (92%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.165); catalogued as COSV60349170; called by muse, mutect2, varscan2
- MS4A1 | c.263T>A p.L88H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61941708; called by muse, varscan2
- MTA1 | c.943-2A>G p.X315_splice | Splice Site (SNP) | VAF 141/257 reads (55%) | catalogued as COSV58755837; called by muse, mutect2, varscan2
- MTMR9 | c.1238G>T p.C413F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs149021500, COSV55310791; called by muse, mutect2, varscan2
- MTREX | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57924143, COSV57924570; called by muse, mutect2, varscan2
- MUC16 | c.43073A>T p.N14358I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as COSV66690087; called by muse, mutect2, varscan2
- MUC5AC | c.14158G>T p.V4720L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV100611573; called by muse, mutect2, varscan2
- MXRA5 | c.3893C>A p.T1298N | Missense Mutation (SNP) | VAF 82/97 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV54225104; called by muse, mutect2, varscan2
- MYBL2 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV53827742; called by muse, mutect2, varscan2
- MYH1 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 96/119 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56844083; called by muse, mutect2, varscan2
- MYH1 | c.2969A>G p.D990G | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV56844091; called by muse, mutect2, varscan2
- MYH11 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55544183; called by muse, mutect2, varscan2
- MYH14 | c.4316G>T p.R1439L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99223959; called by muse, mutect2, varscan2
- MYH2 | c.5415G>C p.E1805D | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55432305; called by muse, mutect2, varscan2
- MYOC | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as rs1220296487, COSV50673917; called by muse, mutect2, varscan2
- NCAM2 | c.2149G>C p.V717L | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as COSV53058499; called by muse, mutect2, varscan2
- NCKAP1L | c.2908T>A p.C970S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53203535; called by muse, mutect2, varscan2
- NCS1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV64962096; called by muse, mutect2, varscan2
- NF1 | c.2004T>C p.D668= | Splice Region (SNP) | VAF 11/28 reads (39%) | catalogued as COSV62194206; called by muse, mutect2, varscan2
- NIPBL | c.4141A>T p.R1381* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV56943465; called by muse, mutect2, varscan2
- NKX2-2 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1469128778, COSV101010621; called by mutect2, varscan2
- NLRP10 | c.53G>T p.S18I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV60778827; called by muse, mutect2, varscan2
- NLRP13 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV61620144; called by muse, mutect2, varscan2
- NLRP2 | c.2634C>G p.N878K | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54752693; called by muse, mutect2, varscan2
- NLRP8 | c.2033C>A p.P678H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52583775; called by muse, mutect2, varscan2
- NMUR1 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV59403555; called by muse, mutect2, varscan2
- NOS1 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs949530892, COSV57607511; called by muse, mutect2, varscan2
- NOX3 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50148887; called by muse, mutect2, varscan2
- NPC1 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99341897; called by muse, mutect2, varscan2
- NPHS1 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62286552; called by muse, mutect2, varscan2
- NUP210L | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV55142301; called by muse, mutect2, varscan2
- OR10J5 | c.722T>A p.V241D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV58384983; called by muse, mutect2, varscan2
- OR11H6 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 108/151 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as rs541140880, COSV59643759, COSV59645043; called by muse, mutect2, varscan2
- OR14C36 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV58600556, COSV58602844; called by muse, mutect2, varscan2
- OR2A25 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 156/180 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68716899; called by muse, mutect2, varscan2
- OR2L13 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV63548677; called by muse, mutect2, varscan2
- OR2L8 | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 118/216 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV61725727, COSV61727548; called by muse, mutect2, varscan2
- OR2M3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101513511; called by muse, mutect2, varscan2
- OR2M4 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60707256, COSV60707352; called by muse, mutect2, varscan2
- OR2T12 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs747214380, COSV58776312; called by muse, mutect2, varscan2
- OR2W3 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV64456103, COSV64458351; called by muse, mutect2, varscan2
- OR4C11 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56352289; called by muse, mutect2, varscan2
- OR4C15 | c.155T>A p.L52* | Nonsense Mutation (SNP) | VAF 89/162 reads (55%) | catalogued as COSV58951251; called by muse, mutect2, varscan2
- OR4D11 | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100506581, COSV57584791; called by muse, mutect2, varscan2
- OR4L1 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 21/130 reads (16%) | catalogued as COSV59848999; called by muse, mutect2, varscan2
- OR4N5 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61320122; called by muse, mutect2, varscan2
- OR56A4 | c.38T>A p.I13K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV58109394; called by muse, mutect2, varscan2
- OR5AR1 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57253971; called by mutect2, varscan2
- OR5F1 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99558736, COSV99558901; called by muse, mutect2, varscan2
- OR5F1 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99558905; called by muse, mutect2, varscan2
- OR6A2 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV60264503; called by muse, mutect2, varscan2
- OR6T1 | c.619T>G p.L207V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV58305784; called by muse, mutect2, varscan2
- OR6Y1 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225341, COSV56928294; called by muse, mutect2, varscan2
- OR7G1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV53317077; called by muse, mutect2, varscan2
- OR8K5 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1246137670, COSV57887987; called by muse, mutect2, varscan2
- OTOA | c.1093T>A p.Y365N (on ENST00000286149; = p.Y351N on NM_144672.4) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV53749603; called by muse, mutect2, varscan2
- OTOGL | c.5521G>A p.D1841N (on ENST00000547103; = p.D1832N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100087847; called by muse, mutect2, varscan2
- PAK5 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.601); catalogued as rs756890556, COSV62021886; called by muse, mutect2, varscan2
- PAK6 | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53044493; called by muse, mutect2, varscan2
- PAMR1 | c.1460T>C p.L487P (on ENST00000619888 / NM_001001991.3; = p.L504P on NM_015430.4) | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53509920; called by muse, mutect2, varscan2
- PAPPA | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV60277991; called by muse, mutect2, varscan2
- PAPPA2 | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV62773662; called by muse, mutect2, varscan2
- PCDH17 | c.2750C>A p.A917E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV64972001; called by muse, mutect2, varscan2
- PCDHA11 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.203); catalogued as rs369212308, COSV56480322; called by muse, mutect2, varscan2
- PCDHB4 | c.209A>T p.D70V | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as COSV52019801; called by muse, mutect2, varscan2
- PCSK2 | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52727102; called by muse, mutect2, varscan2
- PDGFRA | c.1579G>T p.V527L | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV57265134, COSV57266389; called by muse, mutect2, varscan2
- PIEZO2 | c.7987G>T p.G2663W | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53286680, COSV53290417, COSV53292839; called by muse, mutect2, varscan2
- PIK3AP1 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as COSV59530622; called by muse, mutect2, varscan2
- PITPNM3 | c.2409G>T p.Q803H | Missense Mutation (SNP) | VAF 81/103 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52593180; called by muse, mutect2, varscan2
- PLCE1 | c.2717C>A p.A906E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.081); catalogued as rs749091097, COSV53337998; called by muse, mutect2, varscan2
- PLEKHG4B | c.2246G>A p.S749N (on ENST00000283426; = p.S1105N on NM_052909.5) | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs768811829, COSV52044082; called by muse, mutect2, varscan2
- PLEKHM1 | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV69598560; called by muse, mutect2, varscan2
- POLD4 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV56744585; called by muse, mutect2, varscan2
- POM121L12 | c.453G>T p.W151C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); catalogued as COSV68692165, COSV68692309; called by muse, mutect2, varscan2
- POTEH | c.612C>A p.N204K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1203852957, COSV100625216; called by muse, mutect2, varscan2
- POU4F1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV65883793; called by muse, varscan2
- PPFIA2 | c.957C>A p.N319K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV61021732; called by muse, mutect2, varscan2
- PPP1R12A | c.2557A>G p.T853A | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54105671; called by muse, mutect2, varscan2
- PRKCI | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55516889; called by muse, mutect2, varscan2
- PRMT5 | c.1842G>T p.E614D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53544943, COSV99363070; called by muse, mutect2, varscan2
- PRR5L | c.999C>G p.H333Q | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61120302; called by muse, mutect2
- PRRC2B | c.4834G>T p.E1612* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV61934064; called by muse, mutect2, varscan2
- PRSS58 | c.370T>A p.Y124N | Missense Mutation (SNP) | VAF 169/188 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV73488448; called by muse, mutect2, varscan2
- PSD | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV50042021; called by muse, mutect2, varscan2
- PSME4 | c.2459G>T p.C820F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV66363352; called by muse, mutect2, varscan2
- PTPN1 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV63298644; called by muse, varscan2
- PTPN11 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV61005773; called by muse, mutect2, varscan2
- PTPN5 | c.267C>A p.C89* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV62124908; called by muse, mutect2, varscan2
- QARS1 | c.1957G>T p.G653C | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); catalogued as rs1013287948, COSV60274103; called by muse, mutect2, varscan2
- QARS1 | c.1451A>T p.Y484F | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60274111; called by muse, mutect2, varscan2
- R3HCC1L | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54399207; called by muse, mutect2, varscan2
- RAB11FIP5 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV50248011; called by muse, mutect2, varscan2
- RAB2B | c.503A>C p.Y168S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV67235286; called by muse, mutect2, varscan2
- RASIP1 | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55802839; called by muse, mutect2, varscan2
- RBM12B | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 17/339 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs751630925, COSV67897416, COSV67897485; called by muse, mutect2
- RBM45 | c.1393C>T p.P465S (on ENST00000616198 / NM_001365579.1; = p.P463S on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99617998; called by muse, mutect2, varscan2
- RDH10 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53581392, COSV53581501; called by muse, mutect2, varscan2
- REG3A | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV59408515; called by muse, varscan2
- RFC4 | c.50C>G p.T17S | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV56215639; called by muse, mutect2, varscan2
- RHOJ | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57456835; called by muse, mutect2, varscan2
- RNASE11 | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 135/199 reads (68%) | catalogued as COSV60087301; called by muse, mutect2, varscan2
- RNF128 | c.920G>T p.W307L (on ENST00000255499 / NM_194463.2; = p.W281L on NM_024539.3) | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55249261; called by muse, mutect2, varscan2
- RP1L1 | c.5826G>T p.E1942D | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV66752119; called by muse, mutect2, varscan2
- RP1L1 | c.3731A>T p.Y1244F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66752122; called by muse, varscan2
- RP1L1 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV66752130; called by muse, mutect2, varscan2
- RPF1 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.216); catalogued as COSV65705734; called by muse, mutect2, varscan2
- RRM2B | c.49-1G>A p.X17_splice | Splice Site (SNP) | VAF 62/117 reads (53%) | catalogued as COSV52565749; called by muse, mutect2, varscan2
- RSKR | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV56380859; called by muse, mutect2, varscan2
- RTL3 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as COSV58183295; called by muse, mutect2, varscan2
- RXRG | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV63231507; called by muse, mutect2
- RYR1 | c.7049C>G p.A2350G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV62090126; called by muse, mutect2
- RYR1 | c.13904A>T p.E4635V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62090131; called by muse, mutect2, varscan2
- RYR2 | c.3971G>T p.G1324V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV63664929, COSV63703034; called by muse, mutect2, varscan2
- RYR2 | c.10399G>T p.V3467L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV63664936; called by muse, mutect2, varscan2
- S1PR1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59512634; called by muse, mutect2, varscan2
- SAFB2 | c.1153A>C p.K385Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV53040857; called by muse, mutect2, varscan2
- SAGE1 | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.864); catalogued as COSV61011752, COSV61015210; called by muse, mutect2, varscan2
- SAMD15 | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV53625389; called by muse, mutect2, varscan2
- SERPINE2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51455953; called by muse, mutect2, varscan2
- SEZ6L | c.2510G>T p.G837V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV50658425; called by muse, mutect2, varscan2
- SF3A3 | c.539C>G p.A180G | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV65955463; called by muse, mutect2, varscan2
- SHANK3 | c.4579G>T p.A1527S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV53183906; called by muse, mutect2, varscan2
- SHROOM3 | c.5869C>T p.P1957S | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56023833; called by muse, mutect2, varscan2
- SIM1 | c.2184A>T p.R728S | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53489255; called by muse, mutect2, varscan2
- SIPA1L2 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53384205; called by muse, mutect2, varscan2
- SLC10A7 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53880595; called by muse, mutect2, varscan2
- SLC12A5 | c.322G>A p.E108K (on ENST00000454036 / NM_001134771.2; = p.E85K on NM_020708.5) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV54789104; called by muse, mutect2, varscan2
- SLC12A5 | c.1757+1G>A p.X586_splice (on ENST00000454036 / NM_001134771.2; = p.X563_splice on NM_020708.5) | Splice Site (SNP) | VAF 90/292 reads (31%) | catalogued as COSV54789123; called by muse, mutect2, varscan2
- SLC22A12 | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV60571026; called by muse, mutect2
- SLC22A8 | c.593-1G>A p.X198_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV60323870; called by muse, mutect2, varscan2
- SLC24A4 | c.1787C>A p.A596D | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV54107772; called by muse, mutect2, varscan2
- SLC39A12 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.05); catalogued as COSV66195517; called by muse, mutect2, varscan2
- SLC4A3 | c.3530C>A p.A1177D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV56091588; called by mutect2, varscan2
- SLC52A3 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54076746; called by muse, mutect2, varscan2
- SLC5A12 | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54819343; called by muse, mutect2, varscan2
- SLC5A7 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50889110; called by muse, mutect2, varscan2
- SLC6A13 | c.9C>G p.S3R | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58255498; called by muse, mutect2, varscan2
- SLC6A5 | c.4-2A>T p.X2_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV54223962; called by muse, mutect2, varscan2
- SLC7A2 | c.241A>C p.M81L (on ENST00000494857 / NM_001370338.1; = p.M121L on NM_003046.6) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1459039067, COSV50247974; called by muse, mutect2, varscan2
- SLC9A4 | c.2059G>T p.G687* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV54829406; called by muse, mutect2, varscan2
- SLITRK2 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59423368; called by muse, mutect2, varscan2
- SNCA | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV61131943; called by muse, mutect2, varscan2
- SNRPC | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55074853; called by muse, mutect2, varscan2
- SNTG1 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52427046, COSV52434663; called by muse, mutect2, varscan2
- SNTG1 | c.1529C>A p.T510K | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV52427060; called by muse, mutect2, varscan2
- SORBS1 | c.3769A>G p.I1257V (on ENST00000361941 / NM_001034954.2; = p.I649V on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs761469773, COSV53353606; called by muse, mutect2, varscan2
- SORL1 | c.5094G>T p.W1698C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52749885; called by muse, mutect2, varscan2
- SOX5 | c.1165-2A>T p.X389_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV58619898; called by muse, mutect2, varscan2
- SPATA16 | c.1661G>T p.R554L | Missense Mutation (SNP) | VAF 93/117 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63526833, COSV63526919; called by muse, mutect2, varscan2
- SPINK6 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100347004, COSV57777684; called by muse, mutect2, varscan2
- SQOR | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.178); catalogued as COSV52940847; called by muse, mutect2, varscan2
- SRBD1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99765507; called by muse, mutect2, varscan2
- SRBD1 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99765508; called by muse, mutect2, varscan2
- ST8SIA5 | c.887C>A p.A296D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | PolyPhen probably damaging (0.997); catalogued as COSV59330199, COSV59331597; called by muse, mutect2, varscan2
- STARD3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60419046; called by muse, mutect2, varscan2
- STRA8 | c.473T>A p.M158K (on ENST00000275764; = p.M136K on NM_182489.2) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99312640; called by muse, mutect2, varscan2
- STRA8 | c.474G>T p.M158I (on ENST00000275764; = p.M136I on NM_182489.2) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99312645; called by muse, mutect2, varscan2
- STXBP5L | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV56501706, COSV56514543; called by muse, mutect2, varscan2
- STYXL2 | c.3343G>T p.G1115* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV54802378, COSV54808076; called by muse, varscan2
- SYCP2 | c.2365-1G>A p.X789_splice | Splice Site (SNP) | VAF 25/52 reads (48%) | catalogued as COSV62766092; called by muse, mutect2, varscan2
- SYDE2 | c.1895A>T p.K632I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52314263; called by muse, mutect2, varscan2
- SYMPK | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV55609826; called by muse, mutect2, varscan2
- SYT9 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59615046; called by muse, mutect2, varscan2
- TACR3 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM118692, COSV59198536; called by muse, varscan2
- TAF1L | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1264916296, COSV54256517, COSV54258492; called by muse, mutect2, varscan2
- TAS2R1 | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV101225714, COSV66778230; called by muse, mutect2, varscan2
- TAS2R42 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62084386; called by muse, mutect2, varscan2
- TCF20 | c.3667C>G p.L1223V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.15); catalogued as COSV59488675; called by muse, mutect2, varscan2
- TECRL | c.774G>T p.L258= | Splice Region (SNP) | VAF 41/100 reads (41%) | catalogued as rs1378298597, COSV67085681; called by muse, mutect2, varscan2
- TECTA | c.5724G>T p.L1908F | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50689222; called by muse, mutect2, varscan2
- TENM2 | c.6084A>T p.L2028F (on ENST00000518659 / NM_001122679.2; = p.L1789F on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV69123505; called by muse, mutect2, varscan2
- TGFBR3 | c.796G>C p.V266L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.118); catalogued as COSV99283622; called by muse, mutect2, varscan2
- THSD7B | c.1827G>C p.E609D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.096); catalogued as rs991249337, COSV55658080; called by muse, mutect2, varscan2
- TLCD5 | c.44G>T p.G15V (on ENST00000375095 / NM_001198671.2; = p.G37V on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.084); catalogued as COSV58754635, COSV58755923; called by muse, mutect2, varscan2
- TLL1 | c.2037G>T p.W679C | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV50262722; called by muse, mutect2, varscan2
- TLL2 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100780490; called by muse, mutect2, varscan2
- TLR8 | c.1345C>A p.R449S (on ENST00000218032 / NM_138636.5; = p.R467S on NM_016610.4) | Missense Mutation (SNP) | VAF 65/75 reads (87%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780631934, COSV54316619; called by muse, mutect2, varscan2
- TMCO2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as rs1157446249, COSV65646665; called by muse, mutect2, varscan2
- TMCO3 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64806854; called by muse, mutect2, varscan2
- TMEM132D | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV70595147; called by muse, mutect2, varscan2
- TNFRSF14 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV63185856, COSV63188266; called by muse, mutect2, varscan2
- TNR | c.614C>G p.P205R | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54872398, COSV99686657; called by muse, mutect2, varscan2
- TOP2A | c.3447T>G p.N1149K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV70732113; called by muse, mutect2, varscan2
- TPR | c.5993A>T p.N1998I | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV66599637; called by muse, mutect2, varscan2
- TRAF3IP1 | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV64852095; called by muse, mutect2
- TRIM36 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV56688363; called by muse, mutect2, varscan2
- TRIML1 | c.1023C>A p.H341Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286368723, COSV60193444; called by muse, mutect2, varscan2
- TRIML2 | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58714785; called by muse, mutect2, varscan2
- TRIO | c.3332-1G>T p.X1111_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | catalogued as COSV60078182; called by muse, mutect2, varscan2
- TRPC5 | c.1523T>C p.I508T | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53285004; called by muse, mutect2, varscan2
- TSKU | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV60750898; called by muse, mutect2, varscan2
- TTC12 | c.1762A>C p.I588L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV59096776; called by muse, mutect2, varscan2
- TTC23L | c.172A>T p.K58* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV72205767; called by muse, mutect2, varscan2
- TTN | c.98687G>A p.R32896Q (on ENST00000591111; = p.R25472Q on NM_003319.4) | Missense Mutation (SNP) | VAF 56/227 reads (25%) | PolyPhen probably damaging (0.933); catalogued as rs369028576, COSV59904886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.51854C>G p.T17285S (on ENST00000591111; = p.T9861S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | PolyPhen possibly damaging (0.708); catalogued as COSV100628068; called by muse, mutect2, varscan2
- TTN | c.25270A>C p.K8424Q (on ENST00000591111; = p.K7497Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | PolyPhen benign (0.118); catalogued as COSV59904935; called by muse, mutect2, varscan2
- TTN | c.19126G>T p.G6376* (on ENST00000591111; = p.G5449* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/50 reads (72%) | catalogued as COSV59904948; called by muse, mutect2, varscan2
- TTN | c.4378G>C p.V1460L (on ENST00000591111; = p.V1414L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | PolyPhen probably damaging (0.99); catalogued as rs771127151, COSV59904957; called by muse, mutect2, varscan2
- TTN | c.2825C>T p.P942L (on ENST00000591111; = p.P896L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | PolyPhen probably damaging (0.999); catalogued as rs762266215, COSV59904980; called by muse, mutect2, varscan2
- TTN | c.2482C>A p.H828N (on ENST00000591111; = p.H782N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | PolyPhen benign (0.124); catalogued as COSV59905005; called by muse, mutect2, varscan2
- UBR4 | c.9055G>T p.G3019W | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64383347; called by muse, mutect2, varscan2
- UBR4 | c.3643+2T>A p.X1215_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV64383357; called by muse, mutect2, varscan2
- UEVLD | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55577135; called by muse, mutect2, varscan2
- UGT1A3 | c.640A>T p.M214L | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.199); catalogued as COSV59382989; called by muse, mutect2, varscan2
- UNC79 | c.3006C>A p.Y1002* (on ENST00000393151 / NM_001346218.2; = p.Y825* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 142/186 reads (76%) | catalogued as COSV56375649; called by muse, mutect2, varscan2
- USH2A | c.7082A>T p.H2361L | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56332275; called by muse, mutect2, varscan2
- USH2A | c.5916G>C p.E1972D | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV56332289; called by muse, mutect2, varscan2
- USP19 | c.2819G>C p.S940T | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV60045078; called by muse, mutect2, varscan2
- USP28 | c.2804G>T p.G935V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50156025; called by muse, mutect2, varscan2
- USP34 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV68398537; called by muse, mutect2, varscan2
- UST | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as COSV66545811; called by muse, mutect2, varscan2
- VRK2 | c.137-2A>T p.X46_splice | Splice Site (SNP) | VAF 39/102 reads (38%) | catalogued as COSV60874866; called by muse, mutect2, varscan2
- WASF3 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 78/98 reads (80%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV58962823; called by muse, mutect2, varscan2
- WDR77 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as rs1160888914, COSV52384676; called by muse, mutect2, varscan2
- WHRN | c.703A>T p.T235S | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV54327174; called by muse, mutect2, varscan2
- XKR9 | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 38/755 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68772573; called by muse, mutect2
- YAE1 | c.252-2A>G p.X84_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56232634; called by muse, varscan2
- ZBED1 | c.1841C>T p.T614M | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs371214650, COSV58130115; called by muse, mutect2, varscan2
- ZBTB7A | c.1727A>T p.D576V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59326318; called by muse, mutect2, varscan2
- ZCCHC2 | c.1865G>C p.G622A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV54036333; called by muse, mutect2
- ZDBF2 | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs374997578; called by muse, mutect2, varscan2
- ZFP30 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.162); catalogued as COSV63622374; called by muse, mutect2, varscan2
- ZFPM2 | c.2813C>A p.T938N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.185); catalogued as COSV65872662; called by muse, mutect2, varscan2
- ZFYVE26 | c.6616G>T p.G2206C | Missense Mutation (SNP) | VAF 264/338 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61324883; called by muse, mutect2, varscan2
- ZFYVE9 | c.69A>T p.E23D | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV55090459; called by muse, mutect2, varscan2
- ZG16B | c.81+2T>A p.X27_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV66525646; called by mutect2, varscan2
- ZNF225 | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV53470955; called by muse, mutect2, varscan2
- ZNF268 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV57211991; called by muse, mutect2, varscan2
- ZNF341 | c.1440T>A p.C480* (on ENST00000375200 / NM_001282935.1; = p.C473* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV61006253; called by muse, mutect2, varscan2
- ZNF470 | c.115T>C p.W39R | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.856); catalogued as COSV57967728; called by muse, mutect2, varscan2
- ZNF500 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV54787262; called by muse, mutect2, varscan2
- ZNF521 | c.3238C>A p.L1080M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV64122948, COSV64127674; called by muse, mutect2, varscan2
- ZNF536 | c.3857C>G p.T1286R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as COSV62819198; called by muse, mutect2, varscan2
- ZNF543 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.071); catalogued as COSV58626493; called by muse, mutect2, varscan2
- ZNF623 | c.1566G>T p.L522F | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.046); catalogued as COSV71697102; called by muse, mutect2, varscan2
- ZNF677 | c.359T>A p.M120K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1375295763, COSV61719430; called by muse, mutect2, varscan2
- ZNF862 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99783774; called by muse, varscan2
- ZNF93 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV100652420; called by muse, mutect2, varscan2
- ANKRD30A | c.1066del p.E356Kfs*41 (on ENST00000611781; = p.E300Kfs*41 on NM_052997.2) | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- ARPP21 | c.301del p.Q101Kfs*47 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- CDH12 | c.1155C>A p.S385R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); called by mutect2, varscan2
- CDKN1B | c.361dup p.A121Gfs*4 | Frame Shift Ins (INS) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- CEP44 | c.465_471del p.V156Lfs*8 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- COL1A2 | c.1737del p.F579Lfs*103 | Frame Shift Del (DEL) | VAF 41/257 reads (16%) | called by mutect2, pindel, varscan2
- DNAH9 | c.12332_12346del p.E4111_G4115del | In Frame Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel
- DNMT3B | c.1253-22_1256del p.X418_splice | Splice Site (DEL) | VAF 22/94 reads (23%) | called by mutect2, pindel, varscan2
- FBXO41 | c.1072_1087del p.L358Gfs*153 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- IGKV1D-43 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- MED13 | c.2140_2141dup p.D714Efs*16 | Frame Shift Ins (INS) | VAF 13/79 reads (16%) | called by muse*, pindel
- MTUS1 | c.2970del p.A991Hfs*50 (on ENST00000262102 / NM_001363061.1; = p.A157Hfs*50 on NM_020749.4) | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- PCDHGA10 | c.2202del p.G735Afs*2 | Frame Shift Del (DEL) | VAF 56/85 reads (66%) | called by mutect2, pindel, varscan2
- PRKACG | c.541del p.L181Cfs*3 | Frame Shift Del (DEL) | VAF 18/27 reads (67%) | called by mutect2, pindel, varscan2
- PRKCB | c.1929dup p.T644Hfs*2 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- SALL1 | c.185del p.K62Rfs*9 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- SECISBP2L | c.3149_3179del p.E1050Gfs*79 (on ENST00000559471 / NM_001193489.2; = p.E1005Gfs*79 on NM_014701.4) | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel
- SHANK2 | c.5022_5036del p.T1675_T1679del | In Frame Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- SLC5A11 | c.399del p.K134Sfs*27 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel
- SPATA31A1 | c.2126T>A p.L709* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | called by mutect2, varscan2
- STRBP | c.349del p.L117Cfs*2 | Frame Shift Del (DEL) | VAF 55/175 reads (31%) | called by mutect2, pindel, varscan2
- VN1R5 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ZAN | c.8083del p.E2695Rfs*83 | Frame Shift Del (DEL) | VAF 53/91 reads (58%) | called by mutect2, pindel, varscan2
- AGAP2 | c.2403G>C p.R801= (on ENST00000547588 / NM_001122772.2; = p.R465= on NM_014770.4) | Silent (SNP) | VAF 137/348 reads (39%) | catalogued as COSV57726975; called by muse, mutect2, varscan2
- AGMO | c.1128G>A p.L376= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV61106351, COSV61112706; called by muse, mutect2, varscan2
- ALG9 | c.1260G>T p.L420= (on ENST00000614444 / NM_001352418.1; = p.L427= on NM_024740.2) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV67643650; called by muse, mutect2, varscan2
- ANKRD24 | c.3423C>A p.L1141= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV53668039; called by muse, mutect2, varscan2
- ATR | c.2727A>G p.T909= | Silent (SNP) | VAF 124/139 reads (89%) | catalogued as COSV63384319; called by muse, mutect2, varscan2
- BARX2 | c.402C>A p.R134= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV55649459; called by muse, mutect2, varscan2
- BMPER | c.1824C>G p.A608= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV51812358; called by muse, mutect2, varscan2
- BOD1L1 | c.7344A>G p.G2448= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV50006965; called by muse, mutect2, varscan2
- BRIP1 | c.990G>A p.G330= | Silent (SNP) | VAF 75/132 reads (57%) | catalogued as rs1060504320, COSV51994546; ClinVar: likely benign; called by muse, mutect2, varscan2
- CA1 | c.777T>A p.A259= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV56277419; called by muse, mutect2, varscan2
- CAMK4 | c.432C>G p.A144= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV56663287, COSV56668563, COSV99999779; called by muse, mutect2, varscan2
- CD19 | c.1032C>A p.P344= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV61187884; called by muse, mutect2, varscan2
- CD22 | c.1287C>T p.P429= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs888295231, COSV50049752, COSV99322843; called by muse, mutect2, varscan2
- CDC37 | c.810C>T p.R270= | Silent (SNP) | VAF 60/65 reads (92%) | catalogued as COSV55767387; called by muse, mutect2, varscan2
- CDH2 | c.2088G>T p.L696= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV52272731; called by muse, mutect2, varscan2
- CEACAM5 | c.771C>A p.L257= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs782813662, COSV55750866; called by muse, mutect2, varscan2
- CHAT | c.1098G>C p.T366= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV60320623; called by muse, mutect2, varscan2
- CLCN7 | c.720G>T p.G240= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99247605; called by muse, varscan2
- COL3A1 | c.1881T>A p.G627= | Silent (SNP) | VAF 122/166 reads (73%) | catalogued as COSV58582548; called by muse, mutect2, varscan2
- CPS1 | c.3465G>T p.A1155= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs772806744, COSV51803052; called by muse, mutect2, varscan2
- CRYGC | c.504G>T p.R168= | Silent (SNP) | VAF 60/302 reads (20%) | catalogued as COSV52204838; called by muse, mutect2, varscan2
- CSPG4 | c.5898C>A p.L1966= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV57891104; called by muse, mutect2, varscan2
- CTSG | c.759C>A p.T253= | Silent (SNP) | VAF 175/266 reads (66%) | catalogued as COSV53534719, COSV53536287; called by muse, mutect2, varscan2
- CUEDC1 | c.753G>C p.R251= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV64226085; called by muse, mutect2, varscan2
- DCDC1 | c.1800A>G p.A600= | Silent (SNP) | VAF 65/92 reads (71%) | catalogued as rs765332582, COSV60835125; called by muse, mutect2, varscan2
- DDR2 | c.1995T>C p.F665= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as COSV63369512; called by muse, mutect2, varscan2
- DHX34 | c.1932G>C p.T644= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV60894468; called by muse, mutect2, varscan2
- DNAH1 | c.10794G>T p.R3598= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as COSV70226768; called by muse, mutect2, varscan2
- DNAH2 | c.6318C>T p.R2106= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs150195626; called by muse, mutect2, varscan2
- DNAJC22 | c.735A>G p.L245= | Silent (SNP) | VAF 67/172 reads (39%) | catalogued as COSV67711456; called by muse, mutect2, varscan2
- DUSP21 | c.138T>C p.N46= | Silent (SNP) | VAF 53/73 reads (73%) | catalogued as COSV59133646, COSV59134883; called by muse, mutect2, varscan2
- EMILIN3 | c.754C>T p.L252= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV60035222; called by muse, mutect2, varscan2
- ESPN | c.2019G>A p.G673= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV64703817; called by muse, mutect2, varscan2
- ESRRG | c.678G>T p.L226= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV63150918; called by muse, mutect2, varscan2
- FAM110C | c.864G>A p.E288= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV59655714; called by muse, mutect2, varscan2
- FAM160A2 | c.1252C>T p.L418= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV56409729, COSV56410922; called by muse, mutect2, varscan2
- FAM47A | c.528C>T p.P176= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as COSV60500899; called by muse, mutect2, varscan2
- FBN2 | c.7293C>A p.A2431= | Silent (SNP) | VAF 48/69 reads (70%) | catalogued as COSV52494927; called by muse, mutect2, varscan2
- FDFT1 | c.792C>G p.T264= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV55041597; called by muse, mutect2, varscan2
- FDPS | c.501G>A p.V167= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV63113929; called by muse, mutect2, varscan2
- FRMPD4 | c.108C>T p.P36= | Silent (SNP) | VAF 26/27 reads (96%) | catalogued as COSV66211667; called by muse, mutect2, varscan2
- GALNT18 | c.1776G>C p.S592= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs140917604, COSV57144565; called by muse, mutect2, varscan2
- GDNF | c.478T>C p.L160= | Silent (SNP) | VAF 53/195 reads (27%) | catalogued as COSV58478397; called by muse, mutect2, varscan2
- GRID1 | c.2427C>A p.G809= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV60015524; called by muse, mutect2, varscan2
- GUCY1A2 | c.1164T>C p.I388= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV56478969; called by muse, mutect2, varscan2
- HAO2 | c.315C>A p.T105= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV58038014; called by muse, mutect2, varscan2
- HGSNAT | c.639G>T p.L213= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV65532256; called by muse, varscan2
- IGF2 | c.312C>A p.R104= (on ENST00000434045 / NM_001127598.3; = p.R48= on NM_000612.6) | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV56097275; called by muse, mutect2, varscan2
- INPP5J | c.2541C>A p.A847= (on ENST00000331075 / NM_001284285.2; = p.A479= on NM_001002837.2) | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV53207877; called by muse, mutect2, varscan2
- KCNC1 | c.540C>T p.F180= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV56391949; called by muse, mutect2, varscan2
- KEL | c.1947C>T p.Y649= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs902425813, CM151482, COSV62333501; called by muse, mutect2, varscan2
- KIF26A | c.2109G>T p.S703= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100181194, COSV59464704; called by muse, mutect2, varscan2
- KIF2B | c.498G>T p.L166= | Silent (SNP) | VAF 51/75 reads (68%) | catalogued as COSV52127392; called by muse, mutect2, varscan2
- KIRREL3 | c.2292T>G p.S764= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV101375227; called by muse, mutect2, varscan2
- KRTAP9-2 | c.195C>G p.T65= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as COSV66646445; called by muse, mutect2, varscan2
- LHX1 | c.1215G>T p.V405= | Silent (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- LILRA1 | c.819C>A p.P273= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs755921625, COSV52178160; called by muse, mutect2, varscan2
- LILRB3 | c.708C>A p.A236= | Silent (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- LRP1B | c.3888C>T p.H1296= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV67190258; called by muse, mutect2, varscan2
- MACF1 | c.15864G>A p.Q5288= (on ENST00000372915; = p.Q3221= on NM_012090.5) | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as COSV57108234; called by muse, mutect2, varscan2
- MAGEC3 | c.528C>T p.S176= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as rs201684977, COSV53576508; called by muse, mutect2, varscan2
- MDGA2 | c.1797C>A p.A599= (on ENST00000399232 / NM_001113498.2; = p.A301= on NM_182830.4) | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV62080243; called by muse, varscan2
- ME2 | c.1344A>G p.P448= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs750435192, COSV58422352; called by muse, mutect2, varscan2
- MED12L | c.363A>T p.A121= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV56369695; called by muse, mutect2, varscan2
- MEFV | c.789A>T p.L263= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV54818790; called by muse, mutect2, varscan2
- MGAT5B | c.831G>T p.G277= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV56925843; called by muse, mutect2, varscan2
- MROH5 | c.3156C>A p.P1052= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV71300561; called by muse, varscan2
- MTNR1B | c.786C>A p.I262= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV57065466; called by muse, mutect2, varscan2
- MTTP | c.1222C>T p.L408= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV55504018, COSV55506713; called by muse, mutect2, varscan2
- MYH2 | c.4935C>T p.A1645= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1244460006, COSV55432315; called by muse, mutect2, varscan2
- NINL | c.3261T>C p.H1087= | Silent (SNP) | VAF 73/203 reads (36%) | catalogued as COSV53998985; called by muse, mutect2, varscan2
- NLRP8 | c.711C>A p.R237= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV52583766; called by muse, mutect2, varscan2
- NOVA1 | c.1194T>C p.Y398= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs762691909, COSV57472841; called by muse, mutect2, varscan2
- NOX3 | c.1233C>A p.V411= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV50148872; called by muse, mutect2, varscan2
- NRAP | c.2314C>T p.L772= (on ENST00000359988 / NM_001322945.2; = p.L737= on NM_006175.4) | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as rs760795488, COSV63488704; called by muse, mutect2, varscan2
- OR10H1 | c.120G>T p.L40= | Silent (SNP) | VAF 60/82 reads (73%) | catalogued as COSV58470803; called by muse, mutect2, varscan2
- OR1C1 | c.720C>A p.T240= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as COSV68715415; called by muse, mutect2, varscan2
- OR4A16 | c.792C>T p.P264= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59041979; called by muse, mutect2, varscan2
- OR52I1 | c.861C>A p.I287= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as COSV56167661; called by muse, mutect2, varscan2
- OR52R1 | c.477G>T p.V159= | Silent (SNP) | VAF 52/89 reads (58%) | catalogued as rs769775553, COSV100617658, COSV61887494; called by muse, mutect2, varscan2
- OR5AR1 | c.297C>A p.T99= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as rs1160901849, COSV100265771; called by muse, mutect2, varscan2
- OR5D16 | c.813C>T p.H271= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV65721239, COSV65721371; called by muse, mutect2, varscan2
- OR6T1 | c.864C>T p.F288= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as COSV58305774; called by muse, mutect2, varscan2
- OR8G1 | c.63A>T p.P21= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100422641; called by muse, mutect2, varscan2
- ORC3 | c.1290A>T p.P430= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100005461, COSV57638699; called by muse, mutect2, varscan2
- OVCH1 | c.696C>G p.A232= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100548177, COSV58959972; called by muse, mutect2, varscan2
- PADI2 | c.714G>T p.V238= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV64945366; called by muse, mutect2, varscan2
- PAPLN | c.1054C>A p.R352= (on ENST00000554301; = p.R325= on NM_173462.4) | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as COSV53713564, COSV53720685; called by muse, mutect2, varscan2
- PCDHA1 | c.1566C>A p.P522= | Silent (SNP) | VAF 96/122 reads (79%) | catalogued as COSV100974424, COSV65372823, COSV65372847; called by muse, mutect2, varscan2
- PCDHA6 | c.1303C>T p.L435= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV65342115; called by muse, mutect2, varscan2
- PEG3 | c.1344G>T p.G448= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV55626084; called by muse, mutect2, varscan2
- PLXNA4 | c.4992G>A p.K1664= | Silent (SNP) | VAF 137/319 reads (43%) | catalogued as rs760680174, COSV58107240; called by muse, mutect2, varscan2
- POTEF | c.2640G>T p.L880= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV62539961; called by muse, mutect2, varscan2
- PRDM9 | c.1746C>T p.C582= | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as COSV57003059; called by muse, varscan2
- PREX1 | c.1167C>A p.R389= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV64247846, COSV64248237; called by muse, mutect2, varscan2
- PSTK | c.207G>A p.A69= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV64398212; called by mutect2, varscan2
- PTCHD3 | c.237G>T p.S79= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV71256325; called by muse, mutect2, varscan2
- PTPRO | c.297G>T p.V99= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV55504057; called by muse, mutect2, varscan2
- PTPRT | c.3942C>T p.H1314= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as COSV61962709; called by muse, mutect2, varscan2
- PXDNL | c.1113G>T p.L371= | Silent (SNP) | VAF 64/112 reads (57%) | catalogued as COSV62479553; called by muse, mutect2, varscan2
- RASEF | c.1674C>T p.L558= | Silent (SNP) | VAF 63/69 reads (91%) | catalogued as COSV64585952; called by muse, mutect2, varscan2
- RBFOX1 | c.507G>T p.A169= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV60945859, COSV60947282; called by muse, mutect2, varscan2
- RBSN | c.696C>T p.S232= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV53791671; called by muse, mutect2, varscan2
- RNF207 | c.768G>A p.E256= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs961597101, COSV65007200; called by muse, mutect2, varscan2
- RNF44 | c.1143G>A p.V381= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as COSV51269210; called by muse, mutect2, varscan2
- RP1L1 | c.2547T>C p.C849= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as COSV66752127; called by muse, mutect2
- RPL3 | c.291A>T p.R97= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV53364737; called by muse, mutect2, varscan2
- SALL1 | c.3888C>G p.G1296= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV51753809; called by muse, mutect2, varscan2
- SCN8A | c.2580C>A p.T860= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs779745525, COSV61977001; called by muse, mutect2, varscan2
- SEC14L1 | c.1491G>A p.E497= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV66720927; called by muse, mutect2
- SERPINA5 | c.114C>A p.A38= | Silent (SNP) | VAF 56/70 reads (80%) | catalogued as COSV61573619; called by muse, mutect2, varscan2
- SHANK1 | c.6075C>T p.S2025= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs201925001; called by muse, mutect2
- SHC4 | c.100C>A p.R34= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs770928175, COSV60109624, COSV60110349; called by muse, mutect2, varscan2
- SLC17A6 | c.114G>C p.G38= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV54133772; called by muse, mutect2, varscan2
- SLC17A7 | c.1602C>A p.P534= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV55546617; called by muse, mutect2, varscan2
- SLC22A16 | c.1629G>A p.E543= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV57927473; called by muse, mutect2, varscan2
- SLC22A9 | c.744G>A p.L248= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54165962; called by muse, mutect2, varscan2
- SLC26A7 | c.15G>A p.K5= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as rs1339172362, COSV52586976; called by muse, mutect2, varscan2
- SLC40A1 | c.771A>T p.P257= | Silent (SNP) | VAF 115/180 reads (64%) | catalogued as COSV53721962; called by muse, mutect2, varscan2
- SLC44A4 | c.2058C>T p.Y686= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as COSV57665901; called by muse, mutect2, varscan2
- SLC6A11 | c.888C>A p.P296= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as COSV54390227; called by muse, mutect2, varscan2
- SLCO6A1 | c.1260G>T p.V420= | Silent (SNP) | VAF 50/63 reads (79%) | catalogued as COSV65806046; called by muse, mutect2, varscan2
- SLIT3 | c.831C>G p.S277= | Silent (SNP) | VAF 56/77 reads (73%) | catalogued as COSV60594305; called by muse, mutect2, varscan2
- SULF2 | c.528G>T p.R176= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV63414199; called by muse, mutect2, varscan2
- SUSD5 | c.1689G>T p.V563= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs752750298, COSV58875924; called by muse, mutect2, varscan2
- TECTA | c.1110C>T p.R370= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV50689197; called by muse, mutect2, varscan2
- TGFBR3 | c.2413T>C p.L805= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV53022114; called by muse, mutect2, varscan2
- TGFBR3 | c.795G>A p.V265= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99283626; called by muse, mutect2, varscan2
- TRPV4 | c.1707A>C p.A569= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55680245; called by muse, mutect2, varscan2
- TSHZ1 | c.2271G>T p.L757= (on ENST00000580243 / NM_001308210.2; = p.L712= on NM_005786.6) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV59006016; called by muse, mutect2, varscan2
- TTN | c.51855C>A p.T17285= (on ENST00000591111; = p.T9861= on NM_003319.4) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1400002436, COSV100628062; called by muse, mutect2, varscan2
- TTN | c.19479A>T p.A6493= (on ENST00000591111; = p.A5566= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV59904942; called by muse, mutect2, varscan2
- TUBA3C | c.1119G>T p.R373= | Silent (SNP) | VAF 58/71 reads (82%) | catalogued as COSV68027619; called by muse, mutect2, varscan2
- UNC5D | c.1995G>C p.A665= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs145027081, COSV54840707; called by muse, mutect2, varscan2
- USP28 | c.2805G>T p.G935= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs201095177, COSV99136539; called by muse, mutect2, varscan2
- UVRAG | c.141C>T p.N47= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV62101602; called by muse, mutect2, varscan2
- VAV3 | c.2448G>A p.K816= | Silent (SNP) | VAF 85/234 reads (36%) | catalogued as COSV58377681; called by muse, mutect2, varscan2
- VPS35L | c.1629C>T p.Y543= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs895856980, COSV51977727; called by muse, mutect2, varscan2
- WNT3A | c.678C>A p.A226= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV52728971; called by muse, mutect2, varscan2
- WNT6 | c.363G>T p.T121= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1158754265, COSV52109465; called by muse, mutect2
- XKR6 | c.1611G>T p.R537= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV58654621; called by muse, mutect2, varscan2
- XKR7 | c.369G>T p.P123= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV101629297, COSV101629313; called by muse, mutect2, varscan2
- ZAN | c.7185C>T p.V2395= | Silent (SNP) | VAF 51/56 reads (91%) | catalogued as COSV61805570; called by muse, mutect2, varscan2
- ZBTB16 | c.597C>A p.T199= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV60089570; called by muse, mutect2, varscan2
- ZNF195 | c.69C>T p.L23= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs370038920; called by muse, mutect2, varscan2
- ZNF292 | c.6813G>T p.S2271= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60536068; called by muse, mutect2, varscan2
- ZNF37A | c.96G>A p.L32= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV61072639; called by muse, mutect2, varscan2
- ZNF510 | c.1491T>C p.F497= | Silent (SNP) | VAF 136/153 reads (89%) | catalogued as COSV56296318; called by muse, mutect2, varscan2
- FAM74A3 | n.62G>T | RNA (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- IGF2BP2 | c.240-18349G>A | Intron (SNP) | VAF 22/49 reads (45%) | catalogued as rs1243997544, COSV56211283; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129547G>T | Intron (SNP) | VAF 68/77 reads (88%) | catalogued as rs138625130; called by muse, mutect2, varscan2
- MIR485 | n.25G>T | RNA (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- MIR518B | n.13C>A | RNA (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099705 C>T | 5'Flank (SNP) | VAF 26/46 reads (57%) | called by muse, varscan2
- OSGIN1 | n.1899A>G | RNA (SNP) | VAF 41/58 reads (71%) | catalogued as COSV59419363; called by muse, mutect2, varscan2
- PRUNE2 | c.756+35153T>G | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100943286; called by muse, mutect2
- RNF130 | c.443-2039G>A | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as rs371316305; called by muse, mutect2, varscan2
- SNORD114-25 | n.37T>C | RNA (SNP) | VAF 208/244 reads (85%) | called by muse, mutect2, varscan2
- SSPOP | n.2852C>T | RNA (SNP) | VAF 27/34 reads (79%) | catalogued as COSV50486547; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3212A>T | Intron (SNP) | VAF 47/82 reads (57%) | catalogued as COSV100314881; called by muse, mutect2, varscan2
- UBE2C | c.217-65G>T | Intron (SNP) | VAF 78/146 reads (53%) | catalogued as COSV99708774; called by muse, mutect2, varscan2
